Somatic mutation profile of tumor specimen MP2PRT-PAWCSY-TMP1-A (aliquot MP2PRT-PAWCSY-TMP1-A-1-0-D-A821-36) from MP2PRT case MP2PRT-PAWCSY, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Blood; Age at diagnosis: 2.4 years (892 days).
Specimen MP2PRT-PAWCSY-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 01f86f8a-1e66-495a-8132-711a6cc91523.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAWCSY-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAWCSY-NB1-A-1-0-D-A821-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5b561ade-654e-4baf-b4e8-aa6a88e53d8b

The open-access MAF lists 40 somatic variants for this specimen: 27 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 25, Silent 13, Nonstop Mutation 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.57G>C p.L19F | Missense Mutation (SNP) | VAF 106/417 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs121913538, CM155383, COSV55502103, COSV55521217; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- LZTR1 | c.1397G>A p.R466Q | Missense Mutation (SNP) | VAF 49/439 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs587777180, CM140928, COSV53145166; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RBP4 | c.353G>A p.G118E | Missense Mutation (SNP) | VAF 72/260 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1554887443, COSV65160553; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ANKS1B | c.524G>C p.R175T | Missense Mutation (SNP) | VAF 42/341 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs781500367, COSV61364103; called by muse, mutect2, varscan2
- DIDO1 | c.3779C>G p.S1260W | Missense Mutation (SNP) | VAF 219/480 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56630834; called by muse, mutect2, varscan2
- HERC2 | c.2391G>C p.M797I | Missense Mutation (SNP) | VAF 200/548 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV55321077, COSV55330970; called by muse, mutect2, varscan2
- PRR22 | c.870G>A p.M290I | Missense Mutation (SNP) | VAF 19/591 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs866925221; called by muse, mutect2
- SLC8A3 | c.431C>G p.S144C | Missense Mutation (SNP) | VAF 18/422 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100775997; called by muse, mutect2
- AHCTF1 | c.2959G>A p.E987K (on ENST00000366508; = p.E961K on NM_015446.5) | Missense Mutation (SNP) | VAF 67/304 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ARIH1 | c.8C>G p.S3W | Missense Mutation (SNP) | VAF 19/327 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- CAD | c.1063G>C p.E355Q | Missense Mutation (SNP) | VAF 72/292 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CCDC191 | c.1901G>C p.R634T | Missense Mutation (SNP) | VAF 9/248 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.124); called by muse, mutect2
- CCDC92 | c.662T>C p.V221A | Missense Mutation (SNP) | VAF 126/570 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CIAPIN1 | c.220C>G p.L74V | Missense Mutation (SNP) | VAF 92/391 reads (24%) | SIFT tolerated (0.84); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL19A1 | c.94G>C p.E32Q | Missense Mutation (SNP) | VAF 10/244 reads (4%) | SIFT tolerated (0.56); PolyPhen benign (0.007); called by muse, mutect2
- CRAMP1 | c.460G>T p.E154* | Nonsense Mutation (SNP) | VAF 32/301 reads (11%) | called by muse, mutect2, varscan2
- DDX58 | c.2404G>C p.D802H | Missense Mutation (SNP) | VAF 64/250 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- DSP | c.2900C>T p.S967L | Missense Mutation (SNP) | VAF 62/278 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- ESPN | c.2806G>C p.E936Q | Missense Mutation (SNP) | VAF 175/648 reads (27%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- EXPH5 | c.3512G>C p.R1171T | Missense Mutation (SNP) | VAF 58/352 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- LRRK2 | c.2152G>A p.D718N | Missense Mutation (SNP) | VAF 36/366 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- OTOP1 | c.1050C>G p.F350L | Missense Mutation (SNP) | VAF 15/537 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- PNMA2 | c.418G>C p.E140Q | Missense Mutation (SNP) | VAF 46/501 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.473); called by muse, mutect2
- TENM1 | c.6914T>A p.M2305K | Missense Mutation (SNP) | VAF 139/549 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- TMEM158 | c.158C>T p.S53L | Missense Mutation (SNP) | VAF 149/566 reads (26%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.581); called by muse, mutect2, varscan2
- TMEM213 | c.323G>C p.*108Sext*30 | Nonstop Mutation (SNP) | VAF 8/228 reads (4%) | called by muse, mutect2
- TUBB2A | c.115G>C p.D39H | Missense Mutation (SNP) | VAF 41/253 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- CHRFAM7A | c.435C>G p.L145= | Silent (SNP) | VAF 15/642 reads (2%) | called by muse, mutect2
- CIAPIN1 | c.45C>T p.V15= | Silent (SNP) | VAF 76/338 reads (22%) | catalogued as rs373666710; called by muse, mutect2, varscan2
- GDF15 | c.171G>C p.R57= | Silent (SNP) | VAF 130/556 reads (23%) | called by muse, mutect2
- LRRTM4 | c.370C>T p.L124= | Silent (SNP) | VAF 81/315 reads (26%) | catalogued as COSV101297417; called by muse, mutect2, varscan2
- MUC22 | c.5076G>C p.L1692= | Silent (SNP) | VAF 22/432 reads (5%) | called by muse, mutect2
- MYO1A | c.732C>T p.F244= | Silent (SNP) | VAF 15/286 reads (5%) | called by muse, mutect2
- NFRKB | c.2160C>T p.V720= (on ENST00000446488 / NM_001143835.2; = p.V745= on NM_006165.3) | Silent (SNP) | VAF 45/449 reads (10%) | catalogued as rs1323840488; called by muse, mutect2, varscan2
- PCED1A | c.1153C>T p.L385= | Silent (SNP) | VAF 93/362 reads (26%) | catalogued as rs138736783; called by muse, mutect2, varscan2
- PRKD1 | c.843C>A p.P281= | Silent (SNP) | VAF 166/457 reads (36%) | called by muse, mutect2, varscan2
- TCTN3 | c.816C>G p.L272= | Silent (SNP) | VAF 22/346 reads (6%) | called by muse, mutect2
- UCHL5 | c.960G>A p.Q320= | Silent (SNP) | VAF 35/209 reads (17%) | called by muse, mutect2, varscan2
- VCAN | c.10176G>A p.Q3392= | Silent (SNP) | VAF 74/204 reads (36%) | called by muse, mutect2, varscan2
- XYLT2 | c.1599C>G p.L533= | Silent (SNP) | VAF 20/694 reads (3%) | called by muse, mutect2
